Surgical pathology report (de-identified scan), TCGA case TCGA-CM-5348, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-5348-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:
Colon cancer.

Specimens Submitted:
1: SP: COLON; RIGHT HEMICOLECTOMY
2: SP: OMENTUM; RESECTION

DIAGNOSIS:

1. COLON; RIGHT HEMICOLECTOMY:
- TUMOR TYPE: ADENOCARCINOMA.
- HISTOLOGIC GRADE: MODERATELY DIFFERENTIATED.
- TUMOR LOCATION: CECUM.
- TUMOR SIZE: LENGTH IS 3.2 CM, WIDTH IS 4.4 CM, MAXIMAL THICKNESS IS 1.0 CM.
- GROSS CONFIGURATION: POLYPOID.
- TUMOR INVASION: INVASION INTO SUBSEROSA.
- SEROSAL INVOLVEMENT: NOT IDENTIFIED.
- VASCULAR INVASION: NOT IDENTIFIED.
- PERINEURAL INVASION: IDENTIFIED.
- SURGICAL MARGINS (FOR COLONIC TUMORS): FREE OF TUMOR.
- POLYPS (AWAY FROM THE CARCINOMA): NUMBER IDENTIFIED: 3, TYPE IDENTIFIED: TUBULAR ADENOMAS.
- NON-NEOPLASTIC BOWEL: UNREMARKABLE.
- THE PATHOLOGIC STAGE IS (AJCC): pT3.
- LYMPH NODES: NUMBER WITH METASTASES: 1, NUMBER EXAMINED: 19.
- THE PATHOLOGIC STAGE IS (AJCC): pN1.
2. OMENTUM; RESECTION:
- BENIGN ADIPOSE TISSUE.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

** Continued on next page **

[page 2 of 3]
1. The specimen is received fresh, labeled "Right hemicolectomy" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 68 cm in length and 4 cm in circumference at the proximal resected margin. The remaining colon measures 20.1 cm in length with a circumference of 11 cm at the distal resected margin. The attached appendix measures 6.2 cm in length and averages 0.6 cm in diameter, and has serosal adhesions. The intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 7.0 cm in thickness. The specimen is opened to reveal a polypoid and focally ulcerated tumor measuring 3.2 cm in length and 4.4 cm in width, 1.5 cm distal to the ileocecal valve, and 1.8 cm from the closest radial margin. Sectioning shows that the tumor invades into the subserosal fat. The depth of invasion is 1.0 cm grossly. There is also a 0.8 x 0.8 x 0.4 cm polyp, 1.5 cm distal to the tumor. The remaining colonic mucosa shows additional polyps, ranging in size from 0.1 to 0.3 cm. The specimen is submitted for lymph node dissection. Multiple lymph nodes are identified in the attached adipose tissue and are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P-- proximal margin shave
D -- distal margin shave
A -- appendix representative sections
T -- tumor
RM -- radial margin
LP -- largest polyp
SP -- smaller polyps
RS--representative sections, terminal ileum and colon

2. The specimen is received fresh, labeled "Omentum." It consists of a 27 x 18 x 2 cm fragment of adipose tissue consistent with omentum. Serial sectioning reveals an unremarkable cut surface. Representative sections are submitted.

Summary of sections:

O - omentum

Summary of Sections:

Part 1: SP: COLON; RIGHT HEMICOLECTOMY

Block	Sect.	Site	PCs
1		A	3
1		DM	1
8		LN	26

** Continued on next page **

[page 3 of 3]
----- Page 3 of 3

1	LP	2
1	PM	1
1	RM	1
1	RS	2
1	SP	3
4	T	4

Part 2: SP: OMENTUM; RESECTION

Block	Sect.	Site	PCs
1		Q	1

** End of Report **

Source: NCI Genomic Data Commons file 040ca976-b4d4-4500-beac-b4a712962de0 (TCGA-CM-5348.FE4B66D3-242B-4198-9CEA-92D1F2688F22.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).